Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6343, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6343-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6343

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh is a 41g resected prostate 4.5cm from anterior to posterior, 4.0cm from apex to base and 6.0cm from right to left, with attached right and left seminal vesicles and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked follows: Apex-Red, Base-Blue, Right Lateral-Green, Left Lateral-Yellow, Posterior-Black. After removal of the apex and base, the remaining prostate weight is 25g. The specimen is serially sectioned from apex to base to reveal beige tan spongy tissue. No lesions are grossly identified. The attached right and left seminal vesicles are 3.0 x 1.0 x 1.0cm and 1.5 x 1.0 x 0.6cm, respectively, are sectioned to reveal beige tan cystic structure with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 1.2 x 0.4cm and 1.0 x 0.5cm, respectively, are sectioned to reveal beige tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels 1 and 3). The remainder of the specimen is submitted as follows:

- A1: right apex
- A2: left apex
- A3: Level 1 right anterior capsule
- A4: Level 1 right posterior capsule
- A5: Level 1 left anterior capsule
- A6: Level 1 left posterior capsule
- A7: Level 2 right anterior
- A8: Level 2 right posterior
- A9: Level 2 left anterior
- A10: Level 2 left posterior
- A11: Level 3 right anterior capsule
- A12: Level 3 right posterior capsule
- A13: Level 3 left anterior capsule
- A14: Level 3 left posterior capsule
- A15: Level 4 right anterior
- A16: Level 4 right posterior
- A17: Level 4 left anterior
- A18: Level 4 left posterior
- A19-A20: right base with periurethral margin
- A21-A22: left base with periurethral margin
- A23: right lateral base
- A24: left lateral base
- A25: right base
- A26: left base
- A27: right seminal vesicle and vas deferens
- A28: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA , GLEASON'S GRADE 4+3 = 7/10, INVOLVING BOTH RIGHT AND LEFT LOBES OF PROSTATE AND APPROXIMATELY 10% OF THE ENTIRE GLAND (SEE SYNOPTIC REPORT).

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left
Right
Posterior lateral
Apical
Basal

[page 2 of 2]
Anterior
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 10%
Gleason Grade/Sum:: Grade 4 + 3 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: BPH
Basal cell hyperplasia, scattered foci.
Pathological Staging (pTNM): T 2c N X M X

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Prostate Ca.

Source: NCI Genomic Data Commons file 11294f34-2bbe-489d-a904-be61b677686a (TCGA-G9-6343.3D7D837B-A09E-4281-93AF-A789123A9356.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).